Somatic mutation profile of tumor specimen 0DQ80Z from CCDI case PBCETG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.5 years (1,280 days).
Specimen 0DQ80Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e8d5a2e-6f04-4ea7-8e77-8b8d4805385a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7WF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1d2b4ed-2b40-48c0-8d02-5c56e259a7d7

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 130/321 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769110804, COSV61630621; called by muse, mutect2, varscan2
- GOLGA6B | c.1356+2T>C p.X452_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | catalogued as rs1375576588; called by muse, mutect2, varscan2
- ANKRD36C | c.363C>T p.G121= | Silent (SNP) | VAF 30/998 reads (3%) | called by muse, mutect2
- ZCCHC13 | c.414C>T p.H138= | Silent (SNP) | VAF 156/375 reads (42%) | catalogued as rs773322046, COSV100272589; called by muse, varscan2
